Surgical pathology report (de-identified scan), TCGA case TCGA-55-6972, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6972-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient [REDACTED]
MRN [REDACTED]
Date of Service [REDACTED]
Performing Facility [REDACTED]
Ordering Provider [REDACTED]
Result Provider [REDACTED]
Report Name :Surgical Report

Requested by: [REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED] [REDACTED]

==== SPECIMEN DESCRIPTION: =====

- A. RIGHT HILAR LYMPH NODE
- B. RIGHT HILAR LYMPH NODE
- C. N1 LYMPH NODE
- D. RIGHT UPPER LOBE OF LUNG, [REDACTED]
- E. SUBCARINAL LYMPH NODE

==== PRE-OPERATIVE DIAGNOSIS: =====

Right lung mass

==== POST-OPERATIVE DIAGNOSIS: =====

None provided

==== CLINICAL INFORMATION: =====

Right lung lesion; needle biopsy - carcinoma

==== INTRAOPERATIVE CONSULTATION: =====

==== GROSS [REDACTED]

- A. The specimen consists of a lymph node, measuring 0.3 cm in greatest dimension. The external surface is shaggy, with tan-yellow adipose tissue attached. The specimen is submitted intact in one cassette.
- B. The specimen consists of a lymph node, measuring 0.8 x 0.5 x 0.5 cm. The external surface is shaggy, with fibroconnective tissue attached. The specimen is submitted intact in one cassette.
- C. The specimen consists of one lymph node, measuring 1.0 x 0.6 x 0.5 cm. The specimen is bisected and no discrete neoplastic involvement is identified. The specimen is totally submitted in one cassette.
- D/DPC. The specimen consists of the right upper lobe, measuring 16 x 16 x 5.0 cm and weighing 207 grams. The pleural surface is smooth and tan-pink, with two staple lines, measuring 2.5 cm and 5.0 cm in length, on the medial aspect. The specimen is inked black and serially sectioned. Sections show a poorly-circumscribed hemorrhagic area, measuring approximately 4.5 x 4.0 x 4.0 cm. A poorly-defined, ovoid, tan-white, firm nodule, measuring 1.2 x 1.0 x 0.8 cm, is identified within the hemorrhagic area. The hemorrhagic area, away from the nodule, shows cystic degeneration. The nodule appears to be surrounded by a hemorrhagic infarct. The nodule is approximately 1.2 cm from the pleura and 3.5 cm from the bronchial margin. The remaining specimen shows tan-pink spongy pulmonary parenchyma. No discrete satellite lesion is

[page 2 of 3]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Requested by: [REDACTED]

Patient [REDACTED]
MRN [REDACTED]
Date of Service [REDACTED]
Performing Facility [REDACTED]
Ordering Provider [REDACTED]
Result Provider [REDACTED]
Report Name : Surgical Report

identified. The intraparenchymal bronchi are unremarkable. The bronchial and vascular margins in the hilum are free of neoplasm. One possible hilar lymph node, measuring 1.7 cm in greatest dimension, is identified. Sections show moderate anthracosis. Representative sections are submitted in twelve cassettes as follows: cassette 1 - bronchial margin; cassette 2 - vascular margin; cassette 3 - closest staple line; cassette 4 - one hilar lymph node; cassettes 5 through 7 - entire nodule; cassettes 8 through 10 - hemorrhagic area surrounding the nodule; cassettes 11 and 12 - random sections.
E. The specimen consists of three portions of irregular tan-gray soft tissue, measuring 0.7 x 0.7 x 0.1 cm in aggregate. The specimen is submitted intact in one cassette.

==== MICROSCOPIC DESCRIPTION: =====

A, B & C. Three slides are examined. Seen are sections of three benign anthracotic lymph nodes. There is no evidence of metastatic cartilage. Three granulomatous areas are seen in slides B and C.

D/DPC. Twelve slides are examined. Sections representing the grossly described 4.5 cm hemorrhagic area and centrally located nodule reveal a well differentiated adenocarcinoma with papillary features and bronchoalveolar features. There is no involvement of the overlying visceral pleura. There is no definite evidence of lymphovascular space invasion. Sections of the vascular resection margin show no evidence of tumor. Sections of the bronchial resection margin show a focus of carcinoma adjacent to the bronchial cartilage. Also seen is a section of a peribronchial lymph node with no evidence of metastatic carcinoma. Sections of the surrounding lung show no significant pathologic alteration.

E. One slide is examined. Seen are sections of a lymph node. There is marked cautery artifact. There is no definite evidence of carcinoma.

==== FINAL DIAGNOSIS: =====

- A. RIGHT HILAR LYMPH NODE, EXCISION: ONE BENIGN ANTHRACOTIC LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/1)
B. RIGHT HILAR LYMPH NODE, EXCISION: ONE BENIGN LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/1)
C. RIGHT NECK, N1 LYMPH NODE, EXCISION: ONE BENIGN ANTHRACOTIC LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/1)
RIGHT UPPER LOBE OF LUNG, LOBECTOMY:
1. HISTOLOGIC TYPE: PAPILLARY ADENOCARCINOMA WITH BRONCHOALVEOLAR COMPONENT
2. HISTOLOGIC GRADE: WELL DIFFERENTIATED
3. EXTENT OF INVASION: pT2 (TUMOR MEASURES 4.5 CM IN MAXIMUM DIMENSION)

[page 3 of 3]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Requested by: [REDACTED]

Patient

MRN

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name :Surgical Report

-
4. MARGINS: PLEURAL, PARENCHYMAL, BRONCHIAL, AND VASCULAR
RESECTION MARGINS ARE NEGATIVE FOR TUMOR
5. BLOOD/LYMPHATIC VESSEL INVASION: NOT IDENTIFIED
6. REGIONAL LYMPH NODES: ONE BENIGN PERIHILAR LYMPH NODE WITH NO
EVIDENCE OF METASTATIC CARCINOMA (0/1);
ALSO SEE PARTS A THROUGH C
7. DISTANT METASTASIS: NOT ASSESSED
8. TNM STAGE: pT2 NO MX

A-MALIGNANT

[REDACTED]

DATE AND TIME OF REPORT: [REDACTED]

Source: NCI Genomic Data Commons file 6a83265c-c709-4f59-9bc5-e76777a5376b (TCGA-55-6972.7D2C5E22-45D5-404C-97C5-5523EA656D75.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).